CCDI case PBBHYH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/3078a2ff-834b-40c0-b125-6da46bbca139

Demographics
Sex at birth: female; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.6 years (5,326 days).

Biospecimens (3 samples)
- Sample 0D9AJY: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0D9AKM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0D9AKN: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
